Somatic mutation profile of tumor specimen TCGA-AR-A1AK-01A (aliquot TCGA-AR-A1AK-01A-21D-A12Q-09) from TCGA case TCGA-AR-A1AK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 70.7 years (25,825 days).
Specimen TCGA-AR-A1AK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4724491d-573d-40dd-a23d-b0a5420518a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AK-10A (Blood Derived Normal), aliquot TCGA-AR-A1AK-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3427072e-29e5-4f62-8daf-bf20543e2e97

The open-access MAF lists 65 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Nonsense Mutation 7, Frame Shift Ins 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1C1 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 70/527 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1405313151, COSV66499101; called by muse, mutect2, varscan2
- ARHGEF4 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs201813341, COSV58122722; called by muse, mutect2, varscan2
- CARMIL3 | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs763128136, COSV57726484; called by muse, mutect2, varscan2
- CCDC138 | c.1664A>T p.D555V | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54567341; called by muse, mutect2, varscan2
- CFHR4 | c.161A>G p.Y54C (on ENST00000367416 / NM_001201551.2; = p.Y55C on NM_006684.5) | Missense Mutation (SNP) | VAF 209/479 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV52228960; called by muse, mutect2, varscan2
- COIL | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 49/87 reads (56%) | catalogued as COSV99537913; called by muse, mutect2, varscan2
- COL5A3 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV53410851; called by muse, mutect2, varscan2
- COQ10A | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57524748; called by muse, mutect2, varscan2
- CRYBG1 | c.5022G>C p.M1674I | Missense Mutation (SNP) | VAF 99/489 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV64812255; called by muse, mutect2, varscan2
- CTH | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 64/299 reads (21%) | catalogued as rs761864598, COSV61007963; called by muse, mutect2, varscan2
- ELAC2 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749460308, COSV62032731; called by muse, mutect2, varscan2
- FAP | c.1649G>C p.R550T | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV51862008; called by muse, mutect2, varscan2
- FAT1 | c.10025C>A p.T3342K | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV101498694; called by muse, mutect2
- FHDC1 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV52600067; called by muse, mutect2, varscan2
- GCM2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as rs767846876, COSV65275658; called by muse, mutect2, varscan2
- HCN4 | c.2567C>T p.S856F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.723); catalogued as COSV56083611, COSV56086953; called by muse, mutect2, varscan2
- JAK3 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs202027945, COSV71686068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCOR | c.3974G>A p.R1325H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53716048; called by muse, mutect2, varscan2
- LPA | c.5156-1G>A p.X1719_splice | Splice Site (SNP) | VAF 61/225 reads (27%) | catalogued as rs1265685565, COSV60302305; called by muse, mutect2, varscan2
- LY75 | c.2322T>A p.F774L | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV55105792; called by muse, mutect2, varscan2
- MAOA | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772520550, COSV58642967; called by muse, mutect2, varscan2
- MAOB | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65205353; called by muse, mutect2, varscan2
- MTSS1 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as rs762528178, COSV52674772; called by muse, mutect2, varscan2
- MYT1L | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV101219550, COSV67720715, COSV67731287; called by muse, mutect2, varscan2
- NOD1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV56112619; called by muse, mutect2, varscan2
- PC | c.3026C>A p.S1009* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV58992778, COSV58993342, COSV58993758; called by muse, mutect2, varscan2
- PCDHB7 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50769502; called by muse, mutect2, varscan2
- PLA1A | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV56331856; called by muse, mutect2, varscan2
- RAB13 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs202131118, COSV55132158; called by muse, mutect2, varscan2
- SEC24C | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 48/170 reads (28%) | catalogued as COSV59541958, COSV59543404; called by muse, mutect2, varscan2
- SEC24C | c.3230C>T p.S1077F | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59540538, COSV59541973; called by muse, mutect2, varscan2
- SLC30A10 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV63071606; called by muse, mutect2, varscan2
- SRCAP | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.753); catalogued as rs779616437, COSV52672964; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | PolyPhen benign (0.399); catalogued as COSV56571382; called by muse, mutect2, varscan2
- SUN5 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62181250; called by muse, mutect2, varscan2
- SYNE2 | c.10739C>A p.T3580N | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59951620; called by muse, mutect2, varscan2
- TBX4 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99539803; called by muse, mutect2
- TMC7 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58583682; called by muse, mutect2, varscan2
- TRIM45 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs751322882, COSV56713692, COSV56714109; called by muse, mutect2, varscan2
- TRIO | c.5972T>C p.V1991A | Missense Mutation (SNP) | VAF 117/570 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV60084194; called by muse, mutect2, varscan2
- TTN | c.13867G>T p.D4623Y (on ENST00000591111; = p.D3696Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/231 reads (23%) | PolyPhen probably damaging (0.964); catalogued as COSV60075041; called by muse, mutect2, varscan2
- UBE3A | c.1005G>C p.Q335H | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as CD982995, COSV51665264; called by muse, mutect2, varscan2
- WDFY1 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV51789829; called by muse, mutect2, varscan2
- WEE1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55197155; called by muse, mutect2, varscan2
- WNT2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs757215951, COSV55411110; called by muse, mutect2, varscan2
- ZNF660 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 47/223 reads (21%) | catalogued as COSV59549094; called by muse, mutect2, varscan2
- ZRANB3 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV99922404; called by muse, mutect2
- GJA3 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- TBX3 | c.583dup p.E195Gfs*32 (on ENST00000257566 / NM_016569.4; = p.E195Gfs*45 on NM_005996.4) | Frame Shift Ins (INS) | VAF 68/240 reads (28%) | called by mutect2, pindel, varscan2
- XBP1 | c.732dup p.F245Lfs*142 | Frame Shift Ins (INS) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- AC097636.1 | c.117G>A p.Q39= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV71309495; called by muse, mutect2, varscan2
- B3GLCT | c.1221C>T p.L407= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs139927237; called by muse, mutect2, varscan2
- CC2D1B | c.1812C>T p.L604= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs147928724; called by muse, mutect2, varscan2
- CCDC96 | c.717G>A p.R239= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- CPAMD8 | c.4029G>A p.A1343= (on ENST00000651564; = p.A1296= on NM_015692.5) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs774465692, COSV71596615; called by mutect2, varscan2
- CTNNA1 | c.33C>T p.F11= | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as COSV57070654, COSV57074140; called by muse, mutect2, varscan2
- DLX3 | c.342G>A p.E114= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs915621377, COSV71547644; called by muse, mutect2, varscan2
- DNHD1 | c.84C>G p.V28= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54436070; called by muse, mutect2, varscan2
- HEPH | c.2392C>A p.R798= (on ENST00000343002; = p.R531= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as COSV100294500, COSV57964349; called by muse, mutect2, varscan2
- PAICS | c.528G>T p.L176= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV51708726; called by muse, mutect2, varscan2
- SEC24C | c.2397C>T p.L799= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as COSV59540166; called by muse, mutect2, varscan2
- SLC38A3 | c.327C>T p.L109= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV68844012; called by muse, mutect2, varscan2
- TNKS | c.3240C>A p.I1080= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV60058092, COSV60067275; called by muse, mutect2, varscan2
- ZNF131 | c.1641G>A p.R547= (on ENST00000509156 / NM_001330707.2; = p.R513= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV61002585; called by muse, mutect2, varscan2
- C9orf163 | n.1449C>T | RNA (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
